FM case AD968 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/39e6b187-e2d3-454c-a18f-1ff53f09fbfd

Male, 36.5 years: Carcinoma, NOS (ICD-O-3 8010/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
